Somatic mutation profile of tumor specimen TCGA-K4-AAQO-01A (aliquot TCGA-K4-AAQO-01A-11D-A38G-08) from TCGA case TCGA-K4-AAQO, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Anterior wall of bladder; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Age at diagnosis: 56.6 years (20,683 days).
Specimen TCGA-K4-AAQO-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c34f708b-f166-4c03-a60e-2ac5d0bcbc63.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-K4-AAQO-10A (Blood Derived Normal), aliquot TCGA-K4-AAQO-10A-01D-A38J-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/669a953c-105e-4a71-b367-2397b70ef914

The open-access MAF lists 273 somatic variants for this specimen: 210 protein-altering or splice-affecting, 58 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 185, Silent 58, Nonsense Mutation 13, Splice Site 7, Frame Shift Del 2, RNA 2, Splice Region 2, Intron 1, 5'UTR 1, 3'Flank 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACADL | c.692G>C p.S231T | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.181); catalogued as COSV52053507; called by muse, mutect2, varscan2
- ACOX2 | c.302G>A p.R101H | Missense Mutation (SNP) | VAF 17/128 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs769058000, COSV57149114; called by muse, mutect2, varscan2
- ADAMTSL3 | c.3064G>A p.E1022K | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT tolerated (0.29); PolyPhen benign (0.445); catalogued as COSV54441646; called by muse, mutect2, varscan2
- ADAR | c.1756C>T p.H586Y | Missense Mutation (SNP) | VAF 26/128 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52715758; called by muse, mutect2, varscan2
- AKR1C4 | c.902G>A p.R301K | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT tolerated (0.56); PolyPhen benign (0.007); catalogued as COSV54123416; called by muse, mutect2, varscan2
- AMBRA1 | c.194+2T>A p.X65_splice | Splice Site (SNP) | VAF 4/12 reads (33%) | catalogued as COSV54054419; called by muse, mutect2, varscan2
- ANK1 | c.1133C>T p.A378V | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV55882387; called by muse, mutect2, varscan2
- ANKRD23 | c.851G>A p.R284Q | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as rs1306271659, COSV100450297; called by muse, mutect2
- ARHGAP17 | c.721C>G p.Q241E | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.577); catalogued as rs1221532467, COSV51507591; called by muse, mutect2, varscan2
- ARL16 | c.456G>A p.M152I | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as COSV61268018; called by muse, varscan2
- ARMC5 | c.872C>T p.S291F | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.282); catalogued as COSV51656732; called by muse, mutect2, varscan2
- ATG5 | c.466G>A p.G156R | Missense Mutation (SNP) | VAF 6/142 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58347928; called by muse, mutect2
- ATP8B2 | c.1480G>A p.D494N (on ENST00000672630; = p.D461N on NM_001367934.1 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 25/100 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0.073); catalogued as rs1162134040, COSV59246282; called by muse, mutect2, varscan2
- ATR | c.2705C>T p.S902F | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT tolerated (0.73); PolyPhen possibly damaging (0.556); catalogued as COSV63384881, COSV63387625; called by muse, mutect2, varscan2
- BMP15 | c.490T>C p.F164L | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV53140568; called by muse, mutect2, varscan2
- BMT2 | c.996G>C p.R332S | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.089); catalogued as COSV51776940; called by muse, mutect2, varscan2
- BOD1L1 | c.2693G>A p.R898Q | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.926); catalogued as rs375541900, COSV50014131; called by muse, mutect2, varscan2
- BRCA2 | c.7027G>C p.E2343Q | Missense Mutation (SNP) | VAF 28/86 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.39); catalogued as COSV66454323; called by muse, mutect2, varscan2
- BRIP1 | c.1876G>A p.E626K | Missense Mutation (SNP) | VAF 31/117 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52000041; called by muse, mutect2, varscan2
- C12orf4 | c.1210G>C p.E404Q | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.077); catalogued as COSV54207236, COSV54208611; called by muse, mutect2, varscan2
- CA1 | c.505A>G p.K169E | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.636); catalogued as COSV56278704; called by muse, mutect2, varscan2
- CABLES2 | c.492C>G p.I164M | Missense Mutation (SNP) | VAF 85/217 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV54156844; called by muse, mutect2, varscan2
- CALCR | c.1310C>T p.P437L (on ENST00000649521 / NM_001164737.2; = p.P421L on NM_001742.4) | Missense Mutation (SNP) | VAF 14/107 reads (13%) | SIFT tolerated (0.28); PolyPhen benign (0.098); catalogued as COSV64008358; called by muse, mutect2, varscan2
- CAMSAP2 | c.160C>T p.Q54* | Nonsense Mutation (SNP) | VAF 27/108 reads (25%) | catalogued as COSV99372759; called by muse, mutect2, varscan2
- CARNMT1 | c.676C>G p.Q226E | Missense Mutation (SNP) | VAF 15/87 reads (17%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.987); catalogued as rs1466542333, COSV65193649; called by muse, mutect2, varscan2
- CD1E | c.775G>A p.V259I | Missense Mutation (SNP) | VAF 63/141 reads (45%) | SIFT tolerated (0.96); PolyPhen benign (0.003); catalogued as rs764692539, COSV63769980; called by muse, mutect2, varscan2
- CENPT | c.734C>G p.S245C | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.912); catalogued as COSV54649899; called by muse, mutect2, varscan2
- CFAP45 | c.289C>T p.P97S | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV63649156; called by muse, mutect2, varscan2
- CHD6 | c.3705G>A p.M1235I | Missense Mutation (SNP) | VAF 14/199 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.17); catalogued as COSV58556464; called by muse, mutect2
- CIB1 | c.379G>A p.D127N | Missense Mutation (SNP) | VAF 33/105 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV60173680; called by muse, mutect2, varscan2
- COL16A1 | c.2338-1G>A p.X780_splice | Splice Site (SNP) | VAF 18/64 reads (28%) | catalogued as COSV54706540; called by muse, mutect2, varscan2
- CREBBP | c.1618C>T p.Q540* | Nonsense Mutation (SNP) | VAF 15/46 reads (33%) | catalogued as COSV52128159; called by muse, mutect2, varscan2
- CSF3R | c.1552G>A p.V518I | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1207842425, COSV58967028; called by muse, mutect2, varscan2
- CSK | c.816G>A p.G272= | Splice Region (SNP) | VAF 8/47 reads (17%) | catalogued as rs1235811612, COSV54973923; called by muse, mutect2, varscan2
- CSPG5 | c.1441G>A p.E481K | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs200335933, COSV53131200; called by muse, mutect2, varscan2
- CTNNBL1 | c.1306G>T p.E436* | Nonsense Mutation (SNP) | VAF 16/45 reads (36%) | catalogued as rs1349722835, COSV100799265; called by muse, mutect2, varscan2
- CUX2 | c.151G>A p.E51K | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1376228775, COSV55633068; called by muse, mutect2, varscan2
- CYRIA | c.449C>G p.A150G | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.826); catalogued as COSV62865274; called by muse, mutect2, varscan2
- DCLK2 | c.646C>G p.L216V | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV56204819, COSV56209218; called by muse, mutect2, varscan2
- DCLRE1A | c.440C>T p.S147F | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as COSV100800157; called by muse, mutect2
- DCLRE1A | c.224C>T p.S75F | Missense Mutation (SNP) | VAF 100/318 reads (31%) | SIFT tolerated (0.34); PolyPhen benign (0.406); catalogued as COSV63748802; called by muse, mutect2, varscan2
- DCUN1D3 | c.548A>G p.Y183C | Missense Mutation (SNP) | VAF 19/131 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60953452; called by muse, mutect2, varscan2
- DDR2 | c.644C>G p.S215C | Missense Mutation (SNP) | VAF 46/223 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV63371267; called by muse, mutect2, varscan2
- DEFB114 | c.79G>A p.D27N | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.012); catalogued as rs1240354503, COSV59037942, COSV59037991; called by muse, mutect2, varscan2
- DGKB | c.115A>G p.N39D | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1406206386, COSV51784938; called by muse, mutect2, varscan2
- DIAPH3 | c.3292A>T p.R1098W (on ENST00000400324 / NM_001042517.2; = p.R835W on NM_030932.3) | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.998); catalogued as COSV57370985; called by muse, mutect2
- DNAH5 | c.11135C>T p.S3712F | Missense Mutation (SNP) | VAF 21/83 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV54227012; called by muse, mutect2, varscan2
- DNAH8 | c.12584C>G p.S4195C | Missense Mutation (SNP) | VAF 17/174 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.781); catalogued as COSV59448346; called by muse, mutect2, varscan2
- DOT1L | c.766C>T p.R256W | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1171294668, COSV67109891; called by muse, mutect2, varscan2
- DST | c.10897G>C p.D3633H | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.006); catalogued as COSV99750126; called by muse, mutect2
- DTX3L | c.1630G>A p.G544S | Missense Mutation (SNP) | VAF 19/109 reads (17%) | SIFT tolerated (0.62); PolyPhen benign (0.012); catalogued as rs374278659; called by muse, mutect2, varscan2
- DYM | c.1015C>G p.L339V | Missense Mutation (SNP) | VAF 26/85 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.192); catalogued as rs796546957, COSV53985345, COSV99493101; called by muse, mutect2, varscan2
- DZIP1 | c.436G>A p.E146K | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV61266033; called by muse, mutect2, varscan2
- E2F2 | c.485del p.L162Rfs*32 | Frame Shift Del (DEL) | VAF 17/79 reads (22%) | catalogued as COSV62276435; called by mutect2, pindel, varscan2
- EEF1A1 | c.148G>C p.G50R | Missense Mutation (SNP) | VAF 30/93 reads (32%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.947); catalogued as COSV58549715; called by muse, mutect2, varscan2
- EFCAB7 | c.94G>A p.E32K | Missense Mutation (SNP) | VAF 6/71 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.255); catalogued as COSV52132940; called by muse, mutect2
- EIF3I | c.937G>A p.D313N (on ENST00000373586; = p.D315N on NM_003757.3) | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.591); catalogued as rs956661915, COSV61889949; called by muse, mutect2, varscan2
- EIF4G3 | c.400C>T p.P134S | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV51682732, COSV99943978; called by muse, mutect2, varscan2
- EIF6 | c.107+7C>G | Splice Region (SNP) | VAF 119/269 reads (44%) | catalogued as rs763682742, COSV65583114; called by muse, mutect2, varscan2
- EPHA3 | c.742G>T p.G248C | Missense Mutation (SNP) | VAF 50/245 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60706962, COSV60732438; called by muse, mutect2, varscan2
- EPHB1 | c.1651G>A p.V551M | Missense Mutation (SNP) | VAF 11/92 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.272); catalogued as rs368240835; called by muse, mutect2, varscan2
- ERP44 | c.1213G>A p.E405K | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1422338263, COSV52431899; called by muse, mutect2
- FAM120A | c.1852G>A p.E618K | Missense Mutation (SNP) | VAF 15/113 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.132); catalogued as rs1260289690, COSV52905417; called by muse, mutect2, varscan2
- FAM160A2 | c.1085C>G p.S362* | Nonsense Mutation (SNP) | VAF 11/47 reads (23%) | catalogued as COSV99791647; called by muse, mutect2
- FNBP1 | c.883G>A p.V295M | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.526); catalogued as COSV63087685; called by muse, mutect2, varscan2
- FOXJ2 | c.718A>G p.K240E | Missense Mutation (SNP) | VAF 24/149 reads (16%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.824); catalogued as COSV50819012; called by muse, mutect2, varscan2
- FRK | c.305C>G p.S102C | Missense Mutation (SNP) | VAF 26/205 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.856); catalogued as COSV74177087, COSV74177127; called by muse, mutect2, varscan2
- FRY | c.7973C>T p.S2658F | Missense Mutation (SNP) | VAF 30/216 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.183); catalogued as rs775630747, COSV100969793, COSV66570579; called by muse, mutect2, varscan2
- GEMIN5 | c.1856-1G>C p.X619_splice | Splice Site (SNP) | VAF 22/66 reads (33%) | catalogued as COSV53560844; called by muse, mutect2, varscan2
- GFRAL | c.854C>T p.T285M | Missense Mutation (SNP) | VAF 24/118 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs376599512, COSV61228545; called by muse, mutect2, varscan2
- GLRA2 | c.331G>A p.E111K | Missense Mutation (SNP) | VAF 40/90 reads (44%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as COSV54340997; called by muse, mutect2, varscan2
- GNPDA2 | c.688C>A p.Q230K | Missense Mutation (SNP) | VAF 12/97 reads (12%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.995); catalogued as COSV54946825; called by muse, mutect2, varscan2
- GOLGA5 | c.310C>T p.P104S | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT tolerated (0.31); PolyPhen benign (0.005); catalogued as rs1227923629, COSV50833073; called by muse, mutect2, varscan2
- GRM1 | c.2957C>T p.A986V | Missense Mutation (SNP) | VAF 18/131 reads (14%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); catalogued as rs1175647957, COSV51153189; called by muse, mutect2, varscan2
- HERPUD1 | c.494A>G p.Y165C | Missense Mutation (SNP) | VAF 43/277 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs369156763; called by muse, mutect2, varscan2
- HFE | c.617-2A>T p.X206_splice | Splice Site (SNP) | VAF 21/115 reads (18%) | catalogued as COSV58513221; called by muse, mutect2, varscan2
- HHLA2 | c.933C>A p.D311E | Missense Mutation (SNP) | VAF 18/94 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63317483; called by muse, mutect2, varscan2
- HRNR | c.1894C>T p.Q632* | Nonsense Mutation (SNP) | VAF 142/454 reads (31%) | catalogued as COSV100912798; called by muse, varscan2
- IFNK | c.554T>C p.I185T | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1194053261, COSV51780841; called by muse, mutect2, varscan2
- IGLON5 | c.203G>A p.R68H | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs542139381, COSV54536036; called by muse, mutect2
- IRS1 | c.1565G>A p.R522Q | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.018); catalogued as rs373368677; called by muse, mutect2, varscan2
- ITGB2 | c.2004C>G p.S668R (on ENST00000302347; = p.S644R on NM_000211.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.06); catalogued as COSV100186057, COSV56607683; called by muse, mutect2, varscan2
- JAG1 | c.3408C>G p.I1136M | Missense Mutation (SNP) | VAF 12/117 reads (10%) | SIFT tolerated (0.25); PolyPhen benign (0.117); catalogued as COSV54757110; called by muse, mutect2, varscan2
- JAK1 | c.1886G>A p.R629K | Missense Mutation (SNP) | VAF 19/128 reads (15%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.992); catalogued as COSV61091327; called by muse, mutect2, varscan2
- KAT2A | c.502G>C p.E168Q | Missense Mutation (SNP) | VAF 17/108 reads (16%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.513); catalogued as COSV56791023; called by muse, mutect2, varscan2
- KCNH5 | c.202A>T p.M68L | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.456); catalogued as COSV59761164; called by muse, mutect2, varscan2
- KCTD20 | c.596G>C p.R199T | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54803278; called by muse, mutect2, varscan2
- KHSRP | c.745A>T p.I249F | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV67919732; called by muse, mutect2, varscan2
- KIAA0232 | c.3886C>G p.L1296V | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.706); catalogued as COSV56925531, COSV56928792; called by muse, mutect2, varscan2
- KIAA1109 | c.4571G>A p.R1524K | Missense Mutation (SNP) | VAF 31/110 reads (28%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.931); catalogued as COSV52674499; called by muse, mutect2, varscan2
- KIAA1328 | c.1303C>G p.P435A | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as COSV54454407; called by muse, mutect2, varscan2
- KIF1B | c.1933G>C p.E645Q (on ENST00000377086 / NM_001365952.1; = p.E599Q on NM_015074.3) | Missense Mutation (SNP) | VAF 17/87 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.78); catalogued as COSV55809192; called by muse, mutect2, varscan2
- KIF3C | c.489G>C p.K163N | Missense Mutation (SNP) | VAF 27/111 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.174); catalogued as COSV53099500, COSV53099828; called by muse, mutect2, varscan2
- LAG3 | c.98G>A p.W33* | Nonsense Mutation (SNP) | VAF 5/80 reads (6%) | catalogued as COSV99179873; called by muse, mutect2
- LRP6 | c.1069G>A p.E357K | Missense Mutation (SNP) | VAF 16/129 reads (12%) | SIFT tolerated (0.32); PolyPhen benign (0.007); catalogued as COSV53787821; called by muse, mutect2, varscan2
- LRRC36 | c.533C>G p.S178C | Missense Mutation (SNP) | VAF 10/144 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV52079876; called by muse, mutect2
- MECOM | c.62A>G p.Y21C (on ENST00000468789 / NM_001105078.4; = p.Y209C on NM_004991.4) | Missense Mutation (SNP) | VAF 12/114 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV52964928; called by mutect2, varscan2
- MEPE | c.1556C>A p.S519* | Nonsense Mutation (SNP) | VAF 43/177 reads (24%) | catalogued as COSV100734830; called by muse, mutect2, varscan2
- MKI67 | c.251A>T p.H84L | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV64074514; called by muse, mutect2, varscan2
- MLST8 | c.572C>T p.T191I | Missense Mutation (SNP) | VAF 29/85 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.024); catalogued as COSV57028213; called by muse, mutect2, varscan2
- MPHOSPH10 | c.1702G>A p.E568K | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1427788960, COSV99732385; called by muse, mutect2
- MUC16 | c.1996G>A p.G666R | Missense Mutation (SNP) | VAF 35/130 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.361); catalogued as COSV67468441; called by muse, mutect2, varscan2
- MYO9A | c.919A>G p.T307A | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.542); catalogued as rs1435564997, COSV61851445; called by muse, mutect2, varscan2
- NECAB3 | c.482A>T p.E161V | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV55776309; called by muse, mutect2, varscan2
- NHLRC1 | c.19G>C p.E7Q | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.46); PolyPhen benign (0.013); catalogued as COSV61481509; called by muse, mutect2, varscan2
- NNT | c.823G>C p.E275Q | Missense Mutation (SNP) | VAF 10/97 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.839); catalogued as COSV52925259; called by muse, mutect2, varscan2
- NOL6 | c.1383G>A p.M461I | Missense Mutation (SNP) | VAF 13/102 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.91); catalogued as rs764989402, COSV53042015; called by muse, mutect2, varscan2
- NOM1 | c.2152G>C p.E718Q | Missense Mutation (SNP) | VAF 22/149 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.211); catalogued as COSV51980294; called by muse, mutect2, varscan2
- NOS1 | c.232G>A p.D78N | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.213); catalogued as COSV57613216; called by muse, mutect2, varscan2
- NOS2 | c.1840G>C p.E614Q | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT tolerated (0.31); PolyPhen benign (0.053); catalogued as COSV58224041, COSV58226276; called by muse, mutect2, varscan2
- NRBF2 | c.703G>C p.E235Q | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.588); catalogued as COSV53259301; called by muse, mutect2, varscan2
- NT5C1B | c.633G>C p.E211D (on ENST00000359846 / NM_001199086.2; = p.E151D on NM_033253.4) | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as COSV58396116; called by muse, mutect2, varscan2
- OGA | c.30G>T p.L10F | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.094); catalogued as rs780989656, COSV63381768; called by muse, mutect2, varscan2
- OR4C12 | c.455T>A p.L152H | Missense Mutation (SNP) | VAF 46/151 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); catalogued as COSV58859980, COSV58860077; called by muse, mutect2, varscan2
- OR51L1 | c.775G>T p.G259W | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58624193, COSV58624780; called by muse, mutect2, varscan2
- OR6B1 | c.895C>G p.L299V | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.021); catalogued as COSV68770185; called by muse, mutect2, varscan2
- PADI1 | c.145G>A p.E49K | Missense Mutation (SNP) | VAF 23/83 reads (28%) | SIFT tolerated (0.94); PolyPhen benign (0.003); catalogued as COSV64938412; called by muse, mutect2, varscan2
- PARP4 | c.4930G>A p.G1644R | Missense Mutation (SNP) | VAF 29/95 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.685); catalogued as COSV67961892; called by muse, mutect2, varscan2
- PCDHB7 | c.2307C>G p.I769M | Missense Mutation (SNP) | VAF 12/198 reads (6%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.027); catalogued as COSV50755796, COSV50770576; called by muse, mutect2
- PCDHB8 | c.758C>A p.S253Y | Missense Mutation (SNP) | VAF 64/390 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.637); catalogued as COSV50770578; called by muse, varscan2
- PCDHGA4 | c.2359G>T p.E787* | Nonsense Mutation (SNP) | VAF 37/149 reads (25%) | catalogued as COSV99529110, COSV99530563; called by muse, mutect2, varscan2
- PCYT2 | c.550C>T p.R184W | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.586); catalogued as rs1223425798, COSV58710563; called by muse, mutect2, varscan2
- PDE3B | c.2637C>G p.F879L | Missense Mutation (SNP) | VAF 40/95 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV56384031; called by muse, mutect2, varscan2
- PDE4A | c.1820A>G p.D607G (on ENST00000380702 / NM_001111307.2; = p.D368G on NM_006202.3) | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.077); catalogued as COSV53356376; called by muse, mutect2, varscan2
- PHF3 | c.449C>G p.S150* | Nonsense Mutation (SNP) | VAF 27/213 reads (13%) | catalogued as COSV100012794; called by muse, mutect2, varscan2
- PLEKHM2 | c.3028C>T p.R1010C | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs781466914, COSV53816324; called by muse, mutect2, varscan2
- PPP5C | c.1349A>G p.N450S | Missense Mutation (SNP) | VAF 10/114 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50140391; called by muse, mutect2
- PRG4 | c.3125G>C p.R1042T | Missense Mutation (SNP) | VAF 34/138 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV63355552, COSV63355606; called by muse, mutect2, varscan2
- PRRC2C | c.5041G>A p.D1681N (on ENST00000367742; = p.D1679N on NM_015172.4) | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs775467471, COSV100144543; called by muse, varscan2
- PSD | c.2911G>T p.D971Y | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.615); catalogued as COSV50042390; called by muse, mutect2, varscan2
- PSG11 | c.610C>G p.L204V | Missense Mutation (SNP) | VAF 90/485 reads (19%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.517); catalogued as COSV60455318, COSV60455502; called by muse, mutect2, varscan2
- RAC3 | c.173C>T p.T58I | Missense Mutation (SNP) | VAF 11/106 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV60711521; called by muse, mutect2, varscan2
- RFX6 | c.933C>G p.I311M | Missense Mutation (SNP) | VAF 11/95 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.391); catalogued as COSV60585189; called by muse, mutect2, varscan2
- RNASET2 | c.133G>C p.E45Q | Missense Mutation (SNP) | VAF 7/87 reads (8%) | SIFT tolerated (0.59); PolyPhen benign (0.015); catalogued as COSV50351585; called by muse, mutect2
- RNFT1 | c.296T>C p.I99T | Missense Mutation (SNP) | VAF 27/97 reads (28%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as rs772635440, COSV59869809; called by muse, mutect2, varscan2
- ROBO1 | c.1466G>A p.R489K | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs1385573860, COSV71394408, COSV71394574; called by muse, mutect2, varscan2
- SALL1 | c.2455G>C p.D819H | Missense Mutation (SNP) | VAF 101/228 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.205); catalogued as COSV51757970; called by muse, mutect2, varscan2
- SAT2 | c.295G>A p.E99K | Missense Mutation (SNP) | VAF 26/61 reads (43%) | SIFT tolerated (0.05); PolyPhen benign (0.02); catalogued as rs1164172787, COSV52646935; called by muse, mutect2, varscan2
- SCN10A | c.2545G>C p.E849Q | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV71861494; called by muse, mutect2, varscan2
- SCN1A | c.559C>T p.R187W | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1419611654, COSV57671150; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SEMA3A | c.1931C>T p.S644L | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.04); catalogued as COSV54871509; called by muse, mutect2, varscan2
- SEMA6D | c.2108C>T p.S703F (on ENST00000316364 / NM_153618.2; = p.S641F on NM_020858.2) | Missense Mutation (SNP) | VAF 31/113 reads (27%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.791); catalogued as COSV60377711; called by muse, mutect2, varscan2
- SI | c.4703C>T p.P1568L | Missense Mutation (SNP) | VAF 30/229 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52279885, COSV52294175; called by muse, mutect2, varscan2
- SKAP1 | c.199A>T p.S67C | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.751); catalogued as COSV61146915; called by muse, mutect2, varscan2
- SLC12A4 | c.2829G>C p.K943N | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.103); catalogued as COSV50452830; called by muse, mutect2, varscan2
- SLC35D3 | c.857G>A p.G286D | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100090369; called by muse, mutect2
- SLC39A2 | c.892G>A p.G298S | Missense Mutation (SNP) | VAF 36/123 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53869645; called by muse, mutect2, varscan2
- SLC7A14 | c.1300G>C p.E434Q | Missense Mutation (SNP) | VAF 24/97 reads (25%) | SIFT tolerated (0.23); PolyPhen benign (0.39); catalogued as COSV51579018; called by muse, mutect2, varscan2
- SLC7A14 | c.712G>A p.G238R | Missense Mutation (SNP) | VAF 18/90 reads (20%) | SIFT tolerated (0.39); PolyPhen benign (0.327); catalogued as rs141548910, COSV51582460; called by muse, mutect2, varscan2
- SNTG1 | c.454G>T p.E152* | Nonsense Mutation (SNP) | VAF 7/46 reads (15%) | catalogued as COSV99380709; called by muse, mutect2, varscan2
- SOD1 | c.347G>T p.R116L | Missense Mutation (SNP) | VAF 28/122 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54256218, COSV54256299; called by muse, mutect2, varscan2
- SPO11 | c.1174T>C p.F392L | Missense Mutation (SNP) | VAF 13/141 reads (9%) | SIFT tolerated (0.21); PolyPhen benign (0.08); catalogued as COSV61995845, COSV61996227; called by muse, mutect2
- SPOCK1 | c.926G>C p.G309A | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT tolerated (0.29); PolyPhen benign (0.027); catalogued as COSV56450186; called by muse, mutect2, varscan2
- SPSB2 | c.226G>A p.D76N | Missense Mutation (SNP) | VAF 13/118 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as COSV51290179; called by muse, mutect2, varscan2
- STAT5B | c.2078-2A>C p.X693_splice | Splice Site (SNP) | VAF 11/91 reads (12%) | catalogued as COSV53182698; called by muse, mutect2, varscan2
- STEAP3 | c.12G>C p.E4D | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV61529074; called by muse, mutect2, varscan2
- STK36 | c.1106C>T p.S369L | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV55326788; called by muse, mutect2, varscan2
- SULT1A2 | c.352C>G p.L118V | Missense Mutation (SNP) | VAF 23/94 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.795); catalogued as COSV57681764; called by muse, mutect2, varscan2
- SULT1C3 | c.87G>C p.L29F | Missense Mutation (SNP) | VAF 35/84 reads (42%) | SIFT tolerated (0.7); PolyPhen benign (0.003); catalogued as COSV61253106; called by muse, mutect2, varscan2
- SUPT16H | c.296G>C p.G99A | Missense Mutation (SNP) | VAF 29/96 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.147); catalogued as COSV53524902, COSV53525883; called by muse, mutect2, varscan2
- SYNE2 | c.14652A>G p.I4884M | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.87); catalogued as COSV100646475; called by muse, mutect2
- TBATA | c.377C>G p.S126C | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as COSV54719400; called by muse, mutect2, varscan2
- TBC1D4 | c.1885G>C p.E629Q | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.818); catalogued as COSV66487854, COSV66489359; called by muse, mutect2, varscan2
- TBCD | c.217C>G p.L73V | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1164127534, COSV100333255, COSV56182069; called by muse, mutect2, varscan2
- TCF21 | c.481G>A p.E161K | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.036); catalogued as COSV52817680, COSV52818492; called by muse, mutect2, varscan2
- TDRD5 | c.2374T>C p.W792R | Missense Mutation (SNP) | VAF 29/164 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs577467446, COSV54243374; called by muse, mutect2, varscan2
- TEKT5 | c.589C>T p.R197* | Nonsense Mutation (SNP) | VAF 18/65 reads (28%) | catalogued as rs756093532, COSV51588876, COSV51590449; called by muse, mutect2, varscan2
- TENM4 | c.4499G>C p.S1500T | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.014); catalogued as COSV53630825; called by muse, mutect2
- TEX26 | c.400G>A p.E134K | Missense Mutation (SNP) | VAF 36/147 reads (24%) | SIFT tolerated (0.2); PolyPhen benign (0.013); catalogued as COSV104431503, COSV66839927; called by muse, mutect2, varscan2
- TMEM71 | c.134C>G p.S45C | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV100785502; called by muse, mutect2
- TMPRSS9 | c.1196C>T p.S399L (on ENST00000648592; = p.S365L on NM_182973.2) | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.167); catalogued as COSV60227659; called by muse, mutect2, varscan2
- TOP3B | c.250C>T p.Q84* | Nonsense Mutation (SNP) | VAF 29/79 reads (37%) | catalogued as COSV100592270; called by muse, mutect2, varscan2
- TRAFD1 | c.160C>G p.H54D | Missense Mutation (SNP) | VAF 29/126 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57504575; called by muse, varscan2
- TRMT61B | c.1058G>A p.G353D | Missense Mutation (SNP) | VAF 23/120 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.86); catalogued as rs757198928, COSV60258106; called by muse, mutect2, varscan2
- TRPA1 | c.483A>T p.E161D | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.22); catalogued as COSV51562575; called by muse, mutect2, varscan2
- TTC6 | c.640C>T p.H214Y (on ENST00000267368; = p.H1580Y on NM_001310135.3) | Missense Mutation (SNP) | VAF 31/111 reads (28%) | SIFT tolerated (0.46); PolyPhen benign (0.006); catalogued as COSV57449231; called by muse, mutect2, varscan2
- TUBB | c.76G>A p.D26N | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.007); catalogued as COSV58357683; called by muse, mutect2, varscan2
- TUBB | c.580G>C p.E194Q | Missense Mutation (SNP) | VAF 16/106 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (1); catalogued as COSV58357473; called by muse, varscan2
- TUT4 | c.2447A>T p.Q816L | Missense Mutation (SNP) | VAF 22/146 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV57114389, COSV57119295; called by muse, mutect2, varscan2
- TUT7 | c.902A>G p.K301R | Missense Mutation (SNP) | VAF 18/83 reads (22%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as rs371329327; called by muse, mutect2, varscan2
- TWF2 | c.266C>T p.S89L | Missense Mutation (SNP) | VAF 9/97 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as rs376043177, COSV59725955; called by muse, mutect2, varscan2
- UNC13C | c.4169G>T p.G1390V | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs1443238471, COSV99510597; called by muse, mutect2, varscan2
- UNC79 | c.5284G>C p.D1762H (on ENST00000393151 / NM_001346218.2; = p.D1585H on NM_020818.5) | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV56389300; called by muse, mutect2, varscan2
- UNC93A | c.500-2A>G p.X167_splice | Splice Site (SNP) | VAF 10/90 reads (11%) | catalogued as rs765807951, COSV57808658; called by muse, mutect2, varscan2
- USP49 | c.951G>C p.L317F | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT tolerated (0.2); PolyPhen benign (0.009); catalogued as COSV51896717; called by muse, mutect2, varscan2
- UVSSA | c.199G>A p.E67K | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV66229906; called by muse, mutect2, varscan2
- VCAM1 | c.283T>C p.C95R | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54119580; called by muse, mutect2, varscan2
- VCAN | c.505C>G p.Q169E | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.588); catalogued as rs1215389937, COSV54105735; called by muse, mutect2, varscan2
- VIRMA | c.586G>C p.D196H | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.923); catalogued as COSV52585337; called by muse, mutect2
- WDCP | c.1568C>T p.S523L | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.026); catalogued as rs1265903778, COSV54592425; called by muse, mutect2, varscan2
- WDPCP | c.1259G>A p.R420H | Missense Mutation (SNP) | VAF 11/101 reads (11%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.525); catalogued as rs749726622, COSV55416797; called by muse, mutect2, varscan2
- WDR26 | c.1243C>T p.R415W (on ENST00000414423 / NM_001379403.1; = p.R315W on NM_025160.7) | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs748574222, COSV54355591; called by muse, mutect2, varscan2
- WWC1 | c.637G>T p.E213* | Nonsense Mutation (SNP) | VAF 25/114 reads (22%) | catalogued as COSV99514039; called by muse, mutect2, varscan2
- WWP2 | c.1665C>A p.D555E | Missense Mutation (SNP) | VAF 57/139 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as COSV63125180; called by muse, mutect2, varscan2
- WWP2 | c.1784C>T p.S595F | Missense Mutation (SNP) | VAF 74/167 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63125186; called by muse, mutect2, varscan2
- ZFHX4 | c.1108G>C p.E370Q | Missense Mutation (SNP) | VAF 13/85 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.844); catalogued as COSV50675009, COSV50841988; called by muse, mutect2, varscan2
- ZFP36L2 | c.745G>A p.E249K | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.168); catalogued as rs1488231952, COSV56698979, COSV56699574, COSV99143900; called by muse, mutect2
- ZFYVE16 | c.1284C>G p.F428L | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as COSV62015838; called by muse, mutect2, varscan2
- ZNF440 | c.533G>C p.G178A | Missense Mutation (SNP) | VAF 56/199 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.605); catalogued as COSV100407307, COSV58371206; called by muse, mutect2, varscan2
- ZNF440 | c.1075G>A p.E359K | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.241); catalogued as COSV58371215; called by muse, mutect2, varscan2
- ZNF671 | c.118G>A p.E40K | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT tolerated (0.84); PolyPhen benign (0.003); catalogued as COSV58052951; called by muse, mutect2, varscan2
- ZNF676 | c.1252A>G p.I418V (on ENST00000650058; = p.I386V on NM_001001411.3) | Missense Mutation (SNP) | VAF 13/128 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV68093212, COSV68093332; called by muse, mutect2, varscan2
- ZNF808 | c.1651A>G p.N551D | Missense Mutation (SNP) | VAF 30/254 reads (12%) | SIFT tolerated (0.39); PolyPhen benign (0.09); catalogued as COSV63119619; called by muse, mutect2, varscan2
- ZNF831 | c.503G>A p.G168D | Missense Mutation (SNP) | VAF 24/175 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64040595; called by muse, mutect2, varscan2
- ZNRD2 | c.204C>G p.I68M | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT tolerated (0.22); PolyPhen benign (0.328); catalogued as COSV57079531; called by muse, mutect2, varscan2
- CHAF1A | c.2674-1G>A p.X892_splice | Splice Site (SNP) | VAF 3/43 reads (7%) | called by muse, mutect2
- DYSF | c.917del p.G306Afs*32 | Frame Shift Del (DEL) | VAF 39/173 reads (23%) | called by mutect2, pindel, varscan2
- MROH1 | c.3515G>C p.R1172T | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.41); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- RCC1L | c.1088G>A p.G363E | Missense Mutation (SNP) | VAF 23/188 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ZNF317 | c.868_888del p.L290_H296del | In Frame Del (DEL) | VAF 12/61 reads (20%) | called by mutect2, pindel
- ADCY8 | c.966G>A p.V322= | Silent (SNP) | VAF 37/152 reads (24%) | catalogued as COSV53909206; called by muse, mutect2, varscan2
- AK2 | c.279G>A p.L93= (on ENST00000354858; = p.L135= on NM_001625.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 19/118 reads (16%) | catalogued as rs1397171594, COSV61467740; called by muse, mutect2, varscan2
- ARL16 | c.405G>A p.L135= | Silent (SNP) | VAF 6/28 reads (21%) | catalogued as rs1383014432, COSV61268021; called by muse, mutect2
- ARMC6 | c.207G>C p.L69= (on ENST00000392336; = p.L44= on NM_033415.4) | Silent (SNP) | VAF 10/53 reads (19%) | catalogued as COSV54181968; called by muse, mutect2, varscan2
- ATP2C2 | c.2046G>C p.L682= | Silent (SNP) | VAF 11/52 reads (21%) | catalogued as COSV52296343; called by muse, mutect2, varscan2
- ATRX | c.3543C>G p.V1181= | Silent (SNP) | VAF 49/135 reads (36%) | catalogued as rs1269461104, COSV64876971; called by muse, mutect2, varscan2
- BMT2 | c.900G>A p.L300= | Silent (SNP) | VAF 15/93 reads (16%) | catalogued as COSV51776949; called by muse, mutect2, varscan2
- BNC2 | c.3258C>T p.N1086= | Silent (SNP) | VAF 12/80 reads (15%) | catalogued as COSV66166078; called by muse, mutect2, varscan2
- BPIFA3 | c.144C>A p.L48= | Silent (SNP) | VAF 13/71 reads (18%) | catalogued as COSV64925883; called by muse, mutect2, varscan2
- BRD1 | c.1206G>T p.G402= | Silent (SNP) | VAF 78/229 reads (34%) | catalogued as COSV53457598; called by muse, mutect2, varscan2
- CAPN15 | c.2952G>C p.G984= | Silent (SNP) | VAF 6/47 reads (13%) | catalogued as COSV54836163; called by muse, mutect2, varscan2
- CCNG2 | c.798G>A p.K266= | Silent (SNP) | VAF 8/100 reads (8%) | catalogued as COSV60353730; called by muse, mutect2
- CHRND | c.1428G>A p.V476= | Silent (SNP) | VAF 21/72 reads (29%) | catalogued as rs144597817, COSV51319636; called by muse, mutect2, varscan2
- CPED1 | c.1128G>T p.V376= | Silent (SNP) | VAF 5/52 reads (10%) | catalogued as rs1281952633, COSV60002862; called by muse, mutect2
- DCST2 | c.2271C>T p.V757= | Silent (SNP) | VAF 16/64 reads (25%) | catalogued as rs768762307; called by muse, mutect2
- F13B | c.225G>A p.T75= | Silent (SNP) | VAF 24/141 reads (17%) | catalogued as rs545308349, COSV66374000; called by muse, mutect2, varscan2
- FAM124A | c.1545C>T p.C515= (on ENST00000322475 / NM_001242312.2; = p.C551= on NM_145019.4) | Silent (SNP) | VAF 14/66 reads (21%) | catalogued as rs189898463, COSV99696209; called by muse, mutect2, varscan2
- FN3KRP | c.600C>A p.I200= | Silent (SNP) | VAF 21/137 reads (15%) | catalogued as rs371279348; called by muse, mutect2, varscan2
- GMPR | c.198G>A p.V66= | Silent (SNP) | VAF 22/79 reads (28%) | catalogued as COSV52473537; called by muse, mutect2, varscan2
- H3C7 | c.186G>C p.L62= | Silent (SNP) | VAF 52/192 reads (27%) | catalogued as rs199593149, COSV55099937; called by muse, mutect2, varscan2
- HBEGF | c.57A>T p.A19= | Silent (SNP) | VAF 3/22 reads (14%) | catalogued as COSV99138203; called by muse, mutect2
- HBS1L | c.1764T>C p.F588= | Silent (SNP) | VAF 6/94 reads (6%) | catalogued as COSV63201307; called by muse, mutect2
- HECW2 | c.3321G>A p.R1107= | Silent (SNP) | VAF 15/56 reads (27%) | catalogued as COSV53660565; called by muse, mutect2, varscan2
- HSPA4 | c.1167C>T p.V389= | Silent (SNP) | VAF 12/70 reads (17%) | catalogued as COSV59182500; called by muse, mutect2, varscan2
- IGHV5-51 | c.298C>T p.L100= | Silent (SNP) | VAF 54/154 reads (35%) | catalogued as rs183770636; called by muse, mutect2, varscan2
- KCNH8 | c.123C>A p.P41= | Silent (SNP) | VAF 22/210 reads (10%) | catalogued as COSV60464400; called by muse, mutect2, varscan2
- KRTAP4-4 | c.384C>T p.S128= | Silent (SNP) | VAF 27/86 reads (31%) | catalogued as COSV66811330; called by muse, mutect2, varscan2
- LRP3 | c.1548G>A p.L516= | Silent (SNP) | VAF 6/19 reads (32%) | catalogued as COSV99471914; called by muse, mutect2, varscan2
- MUC5B | c.4767C>T p.Y1589= | Silent (SNP) | VAF 5/17 reads (29%) | catalogued as rs1458779625, COSV71592137; called by muse, mutect2, varscan2
- MYO6 | c.2886A>G p.A962= | Silent (SNP) | VAF 4/38 reads (11%) | catalogued as COSV64119127; called by muse, varscan2
- NOA1 | c.2067G>A p.V689= | Silent (SNP) | VAF 27/160 reads (17%) | catalogued as COSV51737120; called by muse, mutect2, varscan2
- NPR2 | c.588C>T p.L196= | Silent (SNP) | VAF 11/50 reads (22%) | catalogued as rs1285029407, COSV61310943; called by muse, mutect2, varscan2
- OSBP | c.351G>A p.L117= | Silent (SNP) | VAF 8/18 reads (44%) | catalogued as rs1396776982, COSV55663047; called by muse, mutect2, varscan2
- PASK | c.972G>T p.A324= | Silent (SNP) | VAF 16/51 reads (31%) | catalogued as COSV52153225; called by muse, mutect2, varscan2
- PAX2 | c.270G>A p.V90= | Silent (SNP) | VAF 26/104 reads (25%) | catalogued as rs1408441464, COSV62291264; called by muse, mutect2, varscan2
- PI4K2B | c.378C>T p.I126= | Silent (SNP) | VAF 12/85 reads (14%) | catalogued as COSV53511445; called by muse, mutect2, varscan2
- PKHD1 | c.6819G>A p.T2273= | Silent (SNP) | VAF 10/79 reads (13%) | catalogued as rs201398262, COSV61877004; called by muse, mutect2, varscan2
- PPM1E | c.1515G>A p.E505= | Silent (SNP) | VAF 31/117 reads (26%) | catalogued as rs541132971, COSV57574677, COSV57579601; called by muse, mutect2, varscan2
- PUM2 | c.2520C>G p.L840= | Silent (SNP) | VAF 15/134 reads (11%) | catalogued as COSV57580913; called by muse, mutect2, varscan2
- RFWD3 | c.1158C>T p.L386= | Silent (SNP) | VAF 8/32 reads (25%) | catalogued as rs772762155, COSV63097858; called by muse, mutect2, varscan2
- RFX1 | c.2133C>T p.I711= | Silent (SNP) | VAF 40/118 reads (34%) | catalogued as rs773269295, COSV54330109; called by muse, mutect2, varscan2
- SGK1 | c.105G>A p.L35= | Silent (SNP) | VAF 7/69 reads (10%) | catalogued as COSV52808929; called by muse, mutect2, varscan2
- SLC12A8 | c.846C>T p.F282= | Silent (SNP) | VAF 4/54 reads (7%) | catalogued as rs954573694, COSV58872946; called by muse, mutect2
- SLC25A47 | c.840C>T p.L280= | Silent (SNP) | VAF 37/146 reads (25%) | catalogued as COSV59924451, COSV59925631; called by muse, mutect2, varscan2
- SLC2A6 | c.1515C>T p.F505= | Silent (SNP) | VAF 8/58 reads (14%) | catalogued as COSV52470080; called by muse, mutect2, varscan2
- SMC5 | c.3271C>A p.R1091= | Silent (SNP) | VAF 17/119 reads (14%) | catalogued as rs149006982, COSV63193024; called by muse, mutect2, varscan2
- SYNRG | c.399C>G p.L133= | Silent (SNP) | VAF 10/110 reads (9%) | catalogued as rs537168614; called by muse, mutect2
- TCHH | c.5100C>T p.L1700= | Silent (SNP) | VAF 21/228 reads (9%) | catalogued as COSV64275018; called by muse, mutect2
- TRAPPC13 | c.9G>C p.V3= | Silent (SNP) | VAF 9/39 reads (23%) | catalogued as COSV51551539; called by muse, mutect2, varscan2
- TRAPPC9 | c.2868G>A p.E956= | Silent (SNP) | VAF 17/58 reads (29%) | catalogued as rs1373612424, COSV66900075; called by muse, mutect2, varscan2
- TRIM37 | c.612G>A p.L204= | Silent (SNP) | VAF 28/118 reads (24%) | catalogued as COSV51883973; called by muse, mutect2, varscan2
- TTN | c.31179G>A p.K10393= (on ENST00000591111; = p.K9466= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 22/61 reads (36%) | catalogued as COSV60082644, COSV60351189; called by muse, mutect2, varscan2
- TUBB | c.675G>C p.L225= | Silent (SNP) | VAF 28/130 reads (22%) | catalogued as COSV58357693; called by muse, varscan2
- TUBB | c.960G>A p.R320= | Silent (SNP) | VAF 28/126 reads (22%) | catalogued as COSV58357698; called by muse, mutect2, varscan2
- TUT1 | c.1218C>G p.V406= | Silent (SNP) | VAF 12/50 reads (24%) | catalogued as COSV53470128; called by muse, mutect2, varscan2
- TYRO3 | c.1014C>T p.L338= | Silent (SNP) | VAF 3/40 reads (8%) | catalogued as COSV55480968; called by muse, mutect2
- ZNF497 | c.1428G>C p.G476= | Silent (SNP) | VAF 5/25 reads (20%) | catalogued as COSV99568098; called by muse, mutect2
- ZNF671 | c.117G>A p.A39= | Silent (SNP) | VAF 14/30 reads (47%) | catalogued as rs747594790, COSV58051842; called by muse, mutect2, varscan2
- AC015802.6 | chr17:76558860 G>A | 3'Flank (SNP) | VAF 22/90 reads (24%) | catalogued as rs1302508466; called by muse, mutect2, varscan2
- OBSCN | c.11659+4244G>A | Intron (SNP) | VAF 19/61 reads (31%) | catalogued as COSV52777364; called by muse, mutect2, varscan2
- RNF217-AS1 | n.2782G>T | RNA (SNP) | VAF 3/16 reads (19%) | called by muse, mutect2
- SNORD115-13 | n.41G>A | RNA (SNP) | VAF 38/436 reads (9%) | called by muse, mutect2
- TBC1D12 | c.-1G>A | 5'UTR (SNP) | VAF 8/30 reads (27%) | catalogued as rs762145762, COSV56552290, COSV56558736; called by muse, mutect2, varscan2
